Somatic mutation profile of tumor specimen C3L-04489-58 (aliquot CPT0300020002) from CPTAC case C3L-04489, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 76.8 years (28,036 days).
Specimen C3L-04489-58: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d972ef9c-6e7a-4534-9502-e722618ce9cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04489-50 (Buccal Cell Normal), aliquot CPT0299980001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44def450-ded6-4dbe-9b63-3bc442dac4c9

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 3'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD1 | c.8668G>A p.E2890K (on ENST00000520002; = p.E2889K on NM_033225.6) | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs199571932, COSV59300242, COSV99064756; called by muse, mutect2, varscan2
- ITGA10 | c.3173G>A p.G1058E | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as rs782067687; called by muse, mutect2
- OVCH1 | c.625A>T p.K209* | Nonsense Mutation (SNP) | VAF 41/207 reads (20%) | catalogued as COSV58968627; called by muse, mutect2, varscan2
- AKAP9 | c.9335G>A p.R3112K (on ENST00000359028; = p.R3088K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MAGEE1 | c.2016G>A p.M672I | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- NLRP8 | c.744G>A p.V248= | Silent (SNP) | VAF 17/440 reads (4%) | catalogued as rs1356287261, COSV52595517; called by muse, mutect2
- PRDM16 | c.1983C>T p.S661= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs764211215, COSV99577747; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF880 | c.609A>G p.Q203= | Silent (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- MLIP | c.*6G>A | 3'UTR (SNP) | VAF 21/114 reads (18%) | catalogued as rs200692573; called by muse, mutect2, varscan2
- TMEM120A | c.564-25G>A | Intron (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
